Somatic mutation profile of tumor specimen TCGA-37-4141-01A (aliquot TCGA-37-4141-01A-02D-1352-08) from TCGA case TCGA-37-4141, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 65.8 years (24,048 days).
Specimen TCGA-37-4141-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75b23b14-469c-4559-9a16-5881c0abb6e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-37-4141-10A (Blood Derived Normal), aliquot TCGA-37-4141-10A-01D-1352-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0987e7ee-3625-42e7-b3e6-fa712048258f

The open-access MAF lists 358 somatic variants for this specimen: 288 protein-altering or splice-affecting, 61 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 245, Silent 61, Nonsense Mutation 17, Frame Shift Del 15, Splice Site 5, Intron 5, Frame Shift Ins 3, RNA 3, Nonstop Mutation 1, In Frame Del 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 62/125 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 71/316 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV52628899, COSV52629050; called by muse, mutect2, varscan2
- AADACL2 | c.442G>C p.A148P | Missense Mutation (SNP) | VAF 247/1016 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as COSV62930366; called by muse, mutect2, varscan2
- ABCA13 | c.2579C>T p.S860F | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70028279; called by muse, mutect2, varscan2
- ABCA5 | c.2111G>A p.W704* | Nonsense Mutation (SNP) | VAF 40/74 reads (54%) | catalogued as COSV67016743; called by muse, mutect2, varscan2
- ADRA2B | c.1257C>G p.S419R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV69787498; called by muse, mutect2
- AK5 | c.577G>T p.A193S (on ENST00000354567 / NM_174858.3; = p.A167S on NM_012093.4) | Missense Mutation (SNP) | VAF 91/266 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV58355530; called by muse, mutect2, varscan2
- AKAP6 | c.4704T>G p.I1568M | Missense Mutation (SNP) | VAF 163/506 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV55213256; called by muse, mutect2, varscan2
- ANGPTL3 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 64/179 reads (36%) | catalogued as COSV52004508; called by muse, mutect2, varscan2
- ANKMY1 | c.1316A>G p.K439R | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV56033779; called by muse, mutect2, varscan2
- ANKS1B | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV61349998; called by muse, mutect2, varscan2
- ASIC3 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52504385; called by muse, mutect2, varscan2
- ASNSD1 | c.1405A>G p.R469G | Missense Mutation (SNP) | VAF 189/381 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV53623679; called by muse, mutect2, varscan2
- ATP11C | c.719G>C p.R240T | Missense Mutation (SNP) | VAF 87/145 reads (60%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV100558232, COSV59563483; called by muse, mutect2, varscan2
- ATRX | c.3403A>T p.R1135W | Missense Mutation (SNP) | VAF 148/221 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.581); catalogued as COSV64876235; called by muse, mutect2, varscan2
- B3GNT3 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59437760; called by muse, mutect2, varscan2
- BRAF | c.1947G>T p.Q649H (on ENST00000288602 / NM_001374244.1; = p.Q609H on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 97/294 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as rs746269606, COSV56059256, COSV56169989; called by muse, mutect2, varscan2
- BRWD3 | c.772G>T p.A258S | Missense Mutation (SNP) | VAF 113/216 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); catalogued as COSV64747677; called by muse, mutect2, varscan2
- BTN3A2 | c.200G>T p.W67L | Missense Mutation (SNP) | VAF 200/731 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62687234; called by muse, mutect2, varscan2
- C12orf40 | c.202+2T>A p.X68_splice | Splice Site (SNP) | VAF 35/81 reads (43%) | catalogued as COSV61132284; called by muse, mutect2, varscan2
- C5orf22 | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 93/348 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as COSV57598354; called by muse, mutect2, varscan2
- C7orf50 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs780594128, COSV62474752; called by muse, mutect2, varscan2
- CACNA1C | c.2143G>T p.G715W | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59715886, COSV59742300; called by muse, mutect2, varscan2
- CADPS | c.3185G>A p.G1062D | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51878848; called by muse, mutect2, varscan2
- CAPN5 | c.1004G>A p.W335* (on ENST00000456580; = p.W295* on NM_004055.5) | Nonsense Mutation (SNP) | VAF 36/75 reads (48%) | catalogued as COSV53687676; called by muse, mutect2, varscan2
- CBLB | c.1342G>T p.D448Y | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51420650, COSV51426325; called by muse, mutect2, varscan2
- CCDC83 | c.892C>G p.Q298E (on ENST00000342404 / NM_001286159.2; = p.Q329E on NM_173556.5) | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV54701621; called by muse, mutect2, varscan2
- CCT5 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 111/457 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54723989; called by muse, mutect2, varscan2
- CDH10 | c.2005G>T p.A669S | Missense Mutation (SNP) | VAF 66/294 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52580064; called by muse, mutect2, varscan2
- CDH12 | c.394G>C p.V132L | Missense Mutation (SNP) | VAF 98/364 reads (27%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.979); catalogued as COSV66403554; called by muse, mutect2, varscan2
- CDH18 | c.503T>A p.V168E | Missense Mutation (SNP) | VAF 197/405 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56920195; called by muse, mutect2, varscan2
- CDH18 | c.346C>A p.L116I | Missense Mutation (SNP) | VAF 138/598 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56920213; called by muse, varscan2
- CDH7 | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59881252; called by muse, mutect2, varscan2
- CLEC4F | c.639C>A p.H213Q | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.554); catalogued as COSV55479243; called by muse, mutect2, varscan2
- CMPK2 | c.994T>A p.Y332N | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56774670; called by muse, mutect2, varscan2
- CNTNAP5 | c.516C>A p.Y172* | Nonsense Mutation (SNP) | VAF 26/52 reads (50%) | catalogued as COSV70484949; called by muse, mutect2
- CNTNAP5 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70484951; called by muse, mutect2
- COG3 | c.1283G>A p.G428E | Missense Mutation (SNP) | VAF 89/317 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.162); catalogued as COSV63072540; called by muse, mutect2, varscan2
- COL11A1 | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62182862; called by muse, mutect2, varscan2
- COL11A2 | c.1417C>T p.Q473* (on ENST00000341947 / NM_080680.3; = p.Q366* on NM_080679.2) | Nonsense Mutation (SNP) | VAF 51/158 reads (32%) | catalogued as COSV59496640; called by muse, mutect2, varscan2
- COL8A1 | c.1457G>A p.G486E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53734109; called by muse, mutect2, varscan2
- CRISP1 | c.20T>G p.L7W | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59993572; called by muse, mutect2, varscan2
- CROCC | c.1996A>G p.R666G | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV65011919; called by muse, mutect2, varscan2
- CRTAC1 | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1243655677, COSV54001290; called by muse, mutect2, varscan2
- CSNK1A1 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 100/144 reads (69%) | catalogued as COSV55794349, COSV55796338; called by muse, mutect2, varscan2
- CST5 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 101/257 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100489725, COSV59014386; called by muse, mutect2, varscan2
- CTBS | c.904A>C p.I302L | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV55362257; called by muse, mutect2, varscan2
- CTDSP1 | c.340T>G p.F114V | Missense Mutation (SNP) | VAF 101/239 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56089871; called by muse, mutect2, varscan2
- CTNNA2 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 95/268 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV63564941; called by muse, mutect2, varscan2
- CTNNBL1 | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 68/214 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as rs370193565; called by muse, mutect2, varscan2
- CUBN | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64715411; called by mutect2, varscan2
- CUBN | c.985G>C p.G329R | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1564519493, COSV64715143, COSV64717388; called by muse, mutect2, varscan2
- CUL3 | c.2192A>T p.K731M | Missense Mutation (SNP) | VAF 58/108 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52364572; called by muse, mutect2, varscan2
- CYC1 | c.629A>T p.Y210F | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59644337; called by muse, mutect2, varscan2
- CYLD | c.2590G>T p.V864F | Missense Mutation (SNP) | VAF 164/448 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772100161, COSV61094557; called by muse, mutect2, varscan2
- CYP11A1 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 54/88 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51431985; called by muse, mutect2, varscan2
- CYP2C19 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 152/460 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV64907689; called by muse, mutect2, varscan2
- DCHS1 | c.5888G>A p.S1963N | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.275); catalogued as COSV55035200; called by muse, mutect2, varscan2
- DCHS1 | c.3709A>T p.T1237S | Missense Mutation (SNP) | VAF 172/293 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.056); catalogued as COSV55035217; called by muse, mutect2, varscan2
- DENND1A | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65325451; called by muse, mutect2, varscan2
- DES | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.067); catalogued as COSV64660294; called by muse, mutect2, varscan2
- DHX9 | c.2198A>G p.K733R | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV62359484; called by muse, mutect2, varscan2
- DLX5 | c.793A>G p.S265G | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1562795806, COSV56032434; called by muse, mutect2, varscan2
- DMXL2 | c.8087A>T p.Q2696L | Missense Mutation (SNP) | VAF 92/138 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51845981; called by muse, mutect2, varscan2
- DNAH11 | c.6296A>T p.D2099V | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60954784; called by muse, mutect2, varscan2
- DNAH11 | c.9505G>T p.V3169L | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV60954796; called by muse, mutect2, varscan2
- DNAH8 | c.10163G>T p.C3388F | Missense Mutation (SNP) | VAF 183/534 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV59424183; called by muse, mutect2, varscan2
- DNAH8 | c.12812T>C p.I4271T | Missense Mutation (SNP) | VAF 115/351 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV59443744; called by muse, mutect2, varscan2
- DNAJC1 | c.403G>C p.D135H | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65376095; called by muse, mutect2, varscan2
- DNMT3B | c.2304A>G p.L768= | Splice Region (SNP) | VAF 100/239 reads (42%) | catalogued as COSV52418284; called by muse, mutect2, varscan2
- DPP10 | c.1222-1G>T p.X408_splice | Splice Site (SNP) | VAF 59/137 reads (43%) | catalogued as COSV59684633, COSV59730084; called by muse, mutect2, varscan2
- EDNRB | c.1285del p.L429Ffs*7 (on ENST00000377211 / NM_001201397.1; = p.L339Ffs*7 on NM_000115.5) | Frame Shift Del (DEL) | VAF 35/119 reads (29%) | catalogued as COSV57528417; called by mutect2, pindel, varscan2
- EFCAB6 | c.3455G>A p.G1152D | Missense Mutation (SNP) | VAF 74/120 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs746270563, COSV53062786; called by muse, mutect2, varscan2
- ELOA2 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 93/296 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV55298593; called by muse, mutect2, varscan2
- EPHB1 | c.1969T>G p.Y657D | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67660924; called by muse, mutect2, varscan2
- EXPH5 | c.2068C>G p.P690A | Missense Mutation (SNP) | VAF 159/383 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV56202060; called by muse, mutect2, varscan2
- EYS | c.1599G>T p.E533D | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.109); catalogued as rs753141908, COSV60984608; called by muse, mutect2, varscan2
- FAM170A | c.829C>G p.Q277E | Missense Mutation (SNP) | VAF 172/337 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0.275); catalogued as COSV58924844, COSV58925046; called by muse, mutect2, varscan2
- FAM180A | c.405C>G p.Y135* | Nonsense Mutation (SNP) | VAF 55/156 reads (35%) | catalogued as COSV58528424; called by muse, mutect2, varscan2
- FARP1 | c.1317G>T p.Q439H | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV60336770; called by muse, mutect2, varscan2
- FBN1 | c.4139G>A p.C1380Y | Missense Mutation (SNP) | VAF 62/98 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1254582017, CM077266, COSV57316015; called by muse, mutect2, varscan2
- FBXO11 | c.628A>G p.M210V (on ENST00000403359 / NM_001190274.2; = p.M126V on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1037057182, COSV57019274; called by muse, mutect2, varscan2
- FBXW5 | c.1450G>T p.V484L | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV56402893; called by muse, mutect2, varscan2
- FDXR | c.790G>T p.D264Y (on ENST00000293195 / NM_024417.5; = p.D270Y on NM_004110.6) | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs751576831, COSV53112033; called by muse, mutect2, varscan2
- FIGN | c.973G>T p.G325W | Missense Mutation (SNP) | VAF 148/298 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV60766369; called by muse, mutect2, varscan2
- FOXP2 | c.1664A>G p.N555S | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63485795; called by muse, mutect2, varscan2
- FREM2 | c.3112G>T p.D1038Y | Missense Mutation (SNP) | VAF 178/505 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs761464358, COSV54836965, COSV54846079; called by muse, mutect2, varscan2
- FREM2 | c.9404G>T p.C3135F | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as rs1002346485, COSV54836986; called by muse, mutect2, varscan2
- FSIP2 | c.18514G>T p.D6172Y | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.78); catalogued as rs200663576; called by muse, mutect2, varscan2
- FYTTD1 | c.673A>T p.T225S | Missense Mutation (SNP) | VAF 85/309 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.989); catalogued as COSV54082574, COSV54083228; called by muse, mutect2, varscan2
- GALNT18 | c.1717G>T p.E573* | Nonsense Mutation (SNP) | VAF 123/210 reads (59%) | catalogued as COSV57148824; called by muse, mutect2, varscan2
- GCH1 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 94/331 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV54301867; called by muse, mutect2, varscan2
- GDF6 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV54624829; called by muse, mutect2, varscan2
- GDF6 | c.88T>A p.S30T | Missense Mutation (SNP) | VAF 74/158 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV54624843; called by muse, mutect2, varscan2
- GJA10 | c.772C>A p.P258T | Missense Mutation (SNP) | VAF 105/273 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.428); catalogued as COSV65354726, COSV65355160, COSV65355365; called by muse, mutect2, varscan2
- GPR153 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV64938426; called by muse, mutect2, varscan2
- GREB1 | c.1577C>G p.A526G | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV52186632; called by muse, mutect2, varscan2
- GRXCR1 | c.293A>G p.N98S | Missense Mutation (SNP) | VAF 165/298 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.321); catalogued as COSV67671661; called by muse, mutect2, varscan2
- HECW2 | c.1394C>G p.S465* | Nonsense Mutation (SNP) | VAF 35/68 reads (51%) | catalogued as COSV53658613; called by muse, mutect2, varscan2
- HIVEP3 | c.5113G>T p.V1705L | Missense Mutation (SNP) | VAF 114/353 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV56015097; called by muse, mutect2, varscan2
- HK2 | c.2729G>A p.R910H | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770307123, COSV51875232; called by muse, mutect2, varscan2
- HOXA10 | c.1019G>T p.R340L | Missense Mutation (SNP) | VAF 78/262 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52228763; called by muse, mutect2, varscan2
- HRNR | c.2416C>T p.H806Y | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.104); catalogued as COSV64257649; called by muse, mutect2, varscan2
- HTRA3 | c.152G>T p.C51F | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56470955; called by muse, varscan2
- HYDIN | c.5620-1G>T p.X1874_splice | Splice Site (SNP) | VAF 61/204 reads (30%) | catalogued as COSV59260549, COSV99993581; called by muse, mutect2, varscan2
- IGHD | c.43T>C p.C15R | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as COSV66655088; called by muse, mutect2, varscan2
- IGHV3-72 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 100/292 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV70409597; called by muse, mutect2, varscan2
- IGLV3-19 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1461450548; called by muse, mutect2, varscan2
- IRS1 | c.2614C>A p.P872T | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59336210; called by muse, mutect2, varscan2
- IRX4 | c.636C>A p.N212K | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51472383; called by muse, mutect2, varscan2
- ITGA10 | c.1834G>A p.G612S | Missense Mutation (SNP) | VAF 132/421 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65197281; called by muse, mutect2, varscan2
- ITGBL1 | c.1394G>A p.G465E | Missense Mutation (SNP) | VAF 149/509 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV65943052; called by muse, mutect2, varscan2
- JPH2 | c.1840C>A p.P614T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV65903233; called by muse, mutect2
- KARS1 | c.556G>T p.G186W | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56692064; called by muse, mutect2, varscan2
- KIDINS220 | c.4174G>T p.A1392S | Missense Mutation (SNP) | VAF 161/518 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.054); catalogued as COSV56753220; called by muse, mutect2, varscan2
- KLHDC7A | c.1410C>G p.D470E | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.379); catalogued as COSV68769680; called by muse, mutect2, varscan2
- KLHL34 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs931517917, COSV65279249; called by muse, mutect2, varscan2
- KRBA1 | c.1765G>C p.D589H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV55441374; called by muse, mutect2, varscan2
- KRT27 | c.311C>A p.A104D | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV56971687; called by muse, mutect2
- KRTAP19-5 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100478576, COSV61859230; called by muse, mutect2, varscan2
- KRTAP24-1 | c.704C>A p.P235H | Missense Mutation (SNP) | VAF 105/293 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100447580, COSV61089428; called by muse, mutect2, varscan2
- L3MBTL3 | c.477A>C p.E159D | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV62386062; called by muse, mutect2, varscan2
- LAMA2 | c.2697G>T p.E899D | Missense Mutation (SNP) | VAF 236/757 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.137); catalogued as COSV70346488; called by muse, mutect2, varscan2
- LAMB3 | c.3004C>A p.Q1002K | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs760837625, COSV50521523; called by muse, mutect2, varscan2
- LARP4 | c.1387C>G p.P463A | Missense Mutation (SNP) | VAF 104/206 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV53322431; called by muse, mutect2, varscan2
- LCT | c.1271C>A p.A424E | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.564); catalogued as COSV51548811; called by muse, mutect2, varscan2
- LRP1B | c.9784C>G p.Q3262E | Missense Mutation (SNP) | VAF 64/312 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV67216537; called by muse, varscan2
- LRP1B | c.2256C>A p.F752L | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV67216539; called by muse, mutect2, varscan2
- LRRC15 | c.1394T>A p.I465N | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV61650045; called by muse, mutect2, varscan2
- LRRC66 | c.1507G>T p.G503C | Missense Mutation (SNP) | VAF 128/245 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV100602934, COSV58633591; called by muse, mutect2, varscan2
- LRRC7 | c.3056C>A p.P1019Q (on ENST00000651989 / NM_001370785.2; = p.P986Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.383); catalogued as COSV50452233, COSV50509157; called by muse, mutect2, varscan2
- LRRTM4 | c.1217del p.P406Qfs*33 | Frame Shift Del (DEL) | VAF 51/208 reads (25%) | catalogued as COSV69140763; called by mutect2, pindel, varscan2
- LYNX1-SLURP2 | c.222C>G p.C74W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58186624; called by muse, mutect2
- MACF1 | c.11252A>G p.K3751R (on ENST00000372915; = p.K1684R on NM_012090.5) | Missense Mutation (SNP) | VAF 63/161 reads (39%) | catalogued as COSV57120109; called by muse, mutect2, varscan2
- MAGEB4 | c.640T>A p.C214S | Missense Mutation (SNP) | VAF 113/180 reads (63%) | SIFT tolerated (0.53); PolyPhen benign (0.145); catalogued as COSV100974920, COSV66775726; called by muse, mutect2, varscan2
- MARCO | c.755T>G p.L252R | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV59054135; called by muse, mutect2, varscan2
- MRGPRF | c.313G>T p.G105W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1444999172, COSV57995838; called by muse, mutect2, varscan2
- MS4A8 | c.249C>A p.H83Q | Missense Mutation (SNP) | VAF 89/255 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55754164; called by muse, mutect2, varscan2
- MSLN | c.1697C>A p.P566Q (on ENST00000382862 / NM_013404.4; = p.P558Q on NM_005823.6) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99558690; called by muse, mutect2, varscan2
- MUC16 | c.4549T>A p.L1517M | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.07); catalogued as COSV67464039; called by muse, mutect2
- MUC17 | c.827C>G p.P276R | Missense Mutation (SNP) | VAF 175/600 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV60287849; called by muse, mutect2, varscan2
- MUC17 | c.4880G>T p.S1627I | Missense Mutation (SNP) | VAF 324/851 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV60287853; called by muse, mutect2, varscan2
- MYNN | c.259C>A p.L87I | Missense Mutation (SNP) | VAF 78/687 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.502); catalogued as COSV57754328, COSV57755513; called by muse, mutect2, varscan2
- MYSM1 | c.841C>G p.Q281E | Missense Mutation (SNP) | VAF 34/668 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.018); catalogued as COSV68977443; called by muse, mutect2
- MYT1L | c.3151C>G p.Q1051E | Missense Mutation (SNP) | VAF 95/257 reads (37%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.465); catalogued as COSV67702362, COSV67703514; called by muse, mutect2, varscan2
- MYT1L | c.1654G>T p.G552C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67719521; called by muse, mutect2, varscan2
- NALCN | c.1346C>A p.S449Y | Missense Mutation (SNP) | VAF 76/202 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV51933965, COSV99213542; called by muse, mutect2, varscan2
- NCKAP1L | c.1390A>T p.S464C | Missense Mutation (SNP) | VAF 113/202 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53206494; called by muse, mutect2, varscan2
- NEUROD6 | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 250/613 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51771357; called by muse, mutect2, varscan2
- NNT | c.802T>A p.S268T | Missense Mutation (SNP) | VAF 191/656 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV52924793, COSV52929929; called by muse, mutect2, varscan2
- NRXN3 | c.2932C>G p.Q978E (on ENST00000335750 / NM_001330195.2; = p.Q605E on NM_004796.6) | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as COSV59745446; called by muse, mutect2, varscan2
- NSUN2 | c.991G>C p.V331L | Missense Mutation (SNP) | VAF 85/323 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52954158; called by muse, mutect2, varscan2
- OR2A2 | c.106C>A p.L36I | Missense Mutation (SNP) | VAF 175/509 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV68871560; called by muse, mutect2, varscan2
- OR2AK2 | c.931T>A p.C311S | Missense Mutation (SNP) | VAF 90/317 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV63552552; called by muse, mutect2, varscan2
- OR2AT4 | c.456T>A p.S152R | Missense Mutation (SNP) | VAF 109/263 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV59406890; called by muse, mutect2, varscan2
- OR4A16 | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 93/308 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1437842296, COSV100125099, COSV59043029; called by muse, mutect2, varscan2
- OR5A2 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57390434, COSV57390932; called by muse, mutect2, varscan2
- OR5B17 | c.631G>C p.V211L | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.168); catalogued as COSV62160267; called by muse, mutect2, varscan2
- OR5I1 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs1260343125, COSV100041338, COSV56886847; called by muse, mutect2, varscan2
- OR6C75 | c.753T>A p.S251R | Missense Mutation (SNP) | VAF 94/170 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV58552152; called by muse, mutect2, varscan2
- OR6F1 | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 119/351 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV57467695; called by muse, mutect2, varscan2
- OTOF | c.2752C>A p.L918I (on ENST00000272371 / NM_194248.3; = p.L171I on NM_004802.4) | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV55502414; called by muse, mutect2, varscan2
- PAPLN | c.731G>T p.R244L (on ENST00000554301; = p.R217L on NM_173462.4) | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV53717566; called by muse, mutect2, varscan2
- PDE1C | c.881G>T p.R294I | Missense Mutation (SNP) | VAF 90/283 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV58513127, COSV58528724; called by muse, mutect2, varscan2
- PDE4DIP | c.1524G>C p.Q508H | Missense Mutation (SNP) | VAF 151/408 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV57694858; called by muse, mutect2, varscan2
- PDILT | c.480C>A p.N160K | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV56701776; called by muse, mutect2, varscan2
- PDZD7 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64646086, COSV64646503; called by muse, mutect2
- PIP4K2C | c.463T>C p.S155P | Missense Mutation (SNP) | VAF 135/213 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV61606122; called by muse, mutect2, varscan2
- PLB1 | c.3030G>C p.Q1010H | Missense Mutation (SNP) | VAF 253/677 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV59824576; called by muse, mutect2, varscan2
- PNLIPRP3 | c.368G>T p.W123L | Missense Mutation (SNP) | VAF 105/298 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65047918; called by muse, mutect2, varscan2
- POLR3E | c.28G>T p.V10L | Missense Mutation (SNP) | VAF 144/361 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV55400335; called by muse, mutect2, varscan2
- PPP1R3D | c.583G>T p.V195L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62564270; called by muse, mutect2, varscan2
- PRB2 | c.617del p.P206Hfs*225 | Frame Shift Del (DEL) | VAF 216/908 reads (24%) | catalogued as COSV66982713; called by pindel, varscan2
- PREX1 | c.2351T>A p.L784Q | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.664); catalogued as COSV64251488; called by muse, mutect2, varscan2
- PRSS36 | c.210C>G p.H70Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.29); catalogued as COSV51637121; called by muse, mutect2, varscan2
- PRUNE2 | c.5824G>A p.V1942M | Missense Mutation (SNP) | VAF 91/155 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV65041318; called by muse, mutect2, varscan2
- PSG9 | c.1000C>A p.L334I | Missense Mutation (SNP) | VAF 234/342 reads (68%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.9); catalogued as COSV52484859; called by muse, mutect2, varscan2
- PTPRE | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 84/275 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV54550530; called by muse, mutect2, varscan2
- REG3G | c.119G>A p.C40Y | Missense Mutation (SNP) | VAF 78/196 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs894967040, COSV55449406; called by muse, mutect2, varscan2
- RELN | c.6602A>G p.N2201S | Missense Mutation (SNP) | VAF 118/318 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.42); catalogued as COSV59000561; called by muse, mutect2, varscan2
- RGS5 | c.544T>C p.*182Qext*1 | Nonstop Mutation (SNP) | VAF 74/184 reads (40%) | catalogued as rs762295521, COSV58352306; called by muse, mutect2, varscan2
- RHCE | c.659G>T p.W220L | Missense Mutation (SNP) | VAF 156/490 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53800326; called by muse, mutect2
- RLN2 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 132/214 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as COSV57731230; called by muse, mutect2, varscan2
- RRAS2 | c.68del p.G23Afs*18 | Frame Shift Del (DEL) | VAF 6/8 reads (75%) | catalogued as COSV56329798, COSV56330700, COSV56332575; called by mutect2, varscan2
- RXRG | c.453C>A p.Y151* | Nonsense Mutation (SNP) | VAF 170/407 reads (42%) | catalogued as COSV63232076; called by muse, mutect2, varscan2
- RYR2 | c.14000G>T p.S4667I | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as rs1057523888, COSV63684161; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAGE1 | c.787C>A p.P263T | Missense Mutation (SNP) | VAF 202/346 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.227); catalogued as COSV61012395, COSV61013241; called by muse, varscan2
- SCN2A | c.4232G>C p.G1411A | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51840344; called by muse, mutect2, varscan2
- SGIP1 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 120/331 reads (36%) | catalogued as COSV52768093; called by muse, mutect2, varscan2
- SGK2 | c.372G>T p.K124N | Missense Mutation (SNP) | VAF 98/274 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58313168; called by muse, mutect2, varscan2
- SHKBP1 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52539714; called by muse, mutect2, varscan2
- SHPRH | c.2290G>T p.E764* | Nonsense Mutation (SNP) | VAF 62/145 reads (43%) | catalogued as COSV51609335; called by muse, mutect2, varscan2
- SIRT7 | c.1022T>G p.F341C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV58711233; called by muse, mutect2
- SIX1 | c.328C>G p.R110G | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CM041438, CM1412918, COSV55959821, COSV55960022, COSV55960951; called by muse, mutect2, varscan2
- SLC17A8 | c.727C>A p.Q243K | Missense Mutation (SNP) | VAF 224/460 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.179); catalogued as COSV60123741; called by muse, varscan2
- SLC2A3 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50002507; called by muse, mutect2, varscan2
- SLC30A1 | c.428A>T p.D143V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100879160; called by muse, mutect2, varscan2
- SLC30A7 | c.473T>G p.V158G | Missense Mutation (SNP) | VAF 321/932 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV63017569; called by muse, mutect2, varscan2
- SLC44A5 | c.2095G>C p.V699L | Missense Mutation (SNP) | VAF 192/623 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV63764377, COSV63765257; called by muse, mutect2, varscan2
- SLC9A9 | c.1871G>T p.G624V | Missense Mutation (SNP) | VAF 129/527 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57218654, COSV57226453; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1939C>G p.L647V (on ENST00000540229 / NM_001371097.1; = p.L586V on NM_001009562.4) | Missense Mutation (SNP) | VAF 177/283 reads (63%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.632); catalogued as COSV67443560; called by muse, mutect2, varscan2
- SLCO2A1 | c.759G>A p.W253* | Nonsense Mutation (SNP) | VAF 123/288 reads (43%) | catalogued as COSV60484287; called by muse, mutect2, varscan2
- SLITRK5 | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 99/290 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV61522745; called by muse, mutect2, varscan2
- SLX4IP | c.1160C>G p.T387S | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV57946495; called by muse, mutect2, varscan2
- SMARCA4 | c.1975G>T p.E659* | Nonsense Mutation (SNP) | VAF 169/349 reads (48%) | catalogued as COSV60793865; called by muse, mutect2, varscan2
- SMARCC1 | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 110/167 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54380279; called by muse, mutect2, varscan2
- SNAI1 | c.191T>A p.V64D | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV54863996; called by muse, mutect2, varscan2
- SNX29 | c.2078G>T p.R693L | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60050101, COSV60058459; called by muse, mutect2, varscan2
- SNX4 | c.344G>T p.S115I | Missense Mutation (SNP) | VAF 68/301 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV52537990; called by muse, mutect2, varscan2
- SNX9 | c.1285G>T p.G429C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67584095; called by muse, mutect2
- SOWAHC | c.1280A>G p.K427R | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV61780175; called by muse, mutect2
- SP2 | c.897G>C p.Q299H | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65064072; called by muse, mutect2
- SPAG11B | c.88C>A p.H30N | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV52499619; called by mutect2, varscan2
- SPANXN2 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 556/1068 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.164); catalogued as COSV65128293; called by muse, varscan2
- SPHKAP | c.1022C>A p.P341Q | Missense Mutation (SNP) | VAF 72/457 reads (16%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.998); catalogued as COSV60877818, COSV60881586; called by muse, mutect2, varscan2
- SPHKAP | c.1021C>A p.P341T | Missense Mutation (SNP) | VAF 73/463 reads (16%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.997); catalogued as COSV60877836, COSV60880014; called by muse, mutect2, varscan2
- SPRY2 | c.143C>G p.A48G | Missense Mutation (SNP) | VAF 100/287 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV65701400; called by muse, mutect2, varscan2
- SPRYD7 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV62524212; called by muse, mutect2, varscan2
- SRCAP | c.3925G>C p.V1309L | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as COSV52672252; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.561C>A p.N187K | Missense Mutation (SNP) | VAF 110/310 reads (35%) | PolyPhen possibly damaging (0.449); catalogued as COSV59565036; called by muse, mutect2, varscan2
- STING1 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 159/225 reads (71%) | catalogued as COSV58172552; called by muse, mutect2, varscan2
- STX11 | c.374C>G p.A125G | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as COSV62449182, COSV62449325; called by muse, mutect2, varscan2
- SYNDIG1 | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 125/376 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV65234741; called by muse, mutect2, varscan2
- TAS2R1 | c.532T>A p.S178T | Missense Mutation (SNP) | VAF 126/500 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.168); catalogued as COSV66778483; called by muse, mutect2, varscan2
- TCTN3 | c.1459A>C p.N487H | Missense Mutation (SNP) | VAF 171/404 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV56447249; called by muse, mutect2, varscan2
- TECRL | c.429G>C p.W143C | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1273815622, COSV67086328, COSV67086998, COSV67088225; called by muse, mutect2, varscan2
- TFAP2D | c.1099A>G p.I367V | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.086); catalogued as rs772704004, COSV50415008, COSV99145901; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1063C>G p.Q355E | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV51512001; called by muse, mutect2, varscan2
- TGM6 | c.726C>A p.Y242* | Nonsense Mutation (SNP) | VAF 46/151 reads (30%) | catalogued as COSV52479839; called by muse, mutect2, varscan2
- THSD7A | c.3319T>A p.C1107S | Missense Mutation (SNP) | VAF 194/549 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV70264430; called by muse, mutect2, varscan2
- TIFAB | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs780767266, COSV72345859; called by mutect2, varscan2
- TMEM47 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as rs771475013, COSV52064587; called by muse, mutect2, varscan2
- TMEM59L | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 161/287 reads (56%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.542); catalogued as COSV53242194; called by muse, mutect2, varscan2
- TNR | c.3248A>C p.K1083T | Missense Mutation (SNP) | VAF 96/280 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54884432; called by muse, varscan2
- TOPORS | c.3035C>T p.P1012L | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV62116864; called by muse, mutect2, varscan2
- TRAF1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 68/104 reads (65%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV65868370; called by muse, mutect2, varscan2
- TRHDE | c.2701T>A p.L901I | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV53843425; called by muse, mutect2, varscan2
- TRIM43 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV55528151; called by muse, mutect2, varscan2
- TRIM49 | c.993G>T p.W331C | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61670760; called by muse, mutect2, varscan2
- TRIM71 | c.2527C>T p.R843C | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); catalogued as rs1211760937, COSV67470830; called by muse, mutect2
- TSPAN12 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 110/261 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56079592; called by muse, mutect2, varscan2
- TTN | c.98749C>T p.R32917C (on ENST00000591111; = p.R25493C on NM_003319.4) | Missense Mutation (SNP) | VAF 193/390 reads (49%) | PolyPhen benign (0.235); catalogued as rs745743825, COSV60041298; called by muse, mutect2, varscan2
- TTN | c.25630A>G p.T8544A (on ENST00000591111; = p.T7617A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | PolyPhen benign (0); catalogued as rs1432990460, COSV60041335; called by muse, mutect2, varscan2
- TTYH3 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51858480, COSV51860067; called by muse, mutect2, varscan2
- TYK2 | c.2404G>T p.A802S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.394); catalogued as COSV53387145; called by muse, mutect2, varscan2
- UACA | c.4062G>C p.Q1354H | Missense Mutation (SNP) | VAF 68/112 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); catalogued as COSV59855591; called by muse, mutect2, varscan2
- UBP1 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 164/276 reads (59%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as COSV52145575; called by muse, mutect2, varscan2
- USH2A | c.7403G>T p.R2468I | Missense Mutation (SNP) | VAF 112/301 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.25); catalogued as COSV56365980; called by muse, mutect2, varscan2
- USP34 | c.1009A>T p.I337L | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV68401067; called by muse, mutect2, varscan2
- VPS35L | c.2028+2T>G p.X676_splice | Splice Site (SNP) | VAF 166/444 reads (37%) | catalogued as COSV51982687; called by muse, mutect2, varscan2
- VWA3B | c.3842C>A p.T1281N | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.125); catalogued as COSV71366144; called by muse, mutect2, varscan2
- XKR3 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 88/273 reads (32%) | catalogued as COSV58886016; called by muse, mutect2, varscan2
- ZAN | c.7637C>A p.A2546D | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as rs777578042, COSV61808719; called by muse, mutect2, varscan2
- ZBBX | c.1477A>T p.I493F | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV56782757, COSV56788705; called by muse, mutect2, varscan2
- ZBTB16 | c.1577C>A p.T526N | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.998); catalogued as COSV60092782; called by muse, mutect2, varscan2
- ZBTB46 | c.1721C>A p.P574Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV99829644; called by muse, mutect2, varscan2
- ZFAND4 | c.1640G>T p.R547L | Missense Mutation (SNP) | VAF 142/378 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV100763160, COSV60858945; called by muse, mutect2, varscan2
- ZFP42 | c.531del p.I178* | Frame Shift Del (DEL) | VAF 162/359 reads (45%) | catalogued as rs1403527187; called by mutect2, pindel, varscan2
- ZKSCAN8 | c.899A>G p.E300G | Missense Mutation (SNP) | VAF 85/230 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57638159; called by muse, mutect2, varscan2
- ZNF135 | c.1452C>A p.H484Q (on ENST00000313434 / NM_001289401.2; = p.H496Q on NM_003436.4) | Missense Mutation (SNP) | VAF 77/131 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774816792, COSV57881928; called by muse, mutect2, varscan2
- ZNF284 | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 89/144 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448870018, COSV69690776, COSV69690977; called by muse, mutect2, varscan2
- ZNF384 | c.1229G>A p.R410Q (on ENST00000361959; = p.R349Q on NM_133476.5) | Missense Mutation (SNP) | VAF 76/135 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1355451508, COSV60530365; called by muse, mutect2, varscan2
- ZNF521 | c.644G>C p.S215T | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV64126635, COSV64131625; called by muse, mutect2, varscan2
- ZNF560 | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 136/208 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as rs866296523, COSV56867701; called by muse, mutect2, varscan2
- ZNF611 | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 336/560 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60540735; called by muse, mutect2, varscan2
- ZNF705A | c.764G>A p.C255Y | Missense Mutation (SNP) | VAF 216/405 reads (53%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs777361497, COSV63733123; called by muse, mutect2, varscan2
- ZNF93 | c.624A>T p.K208N | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV59375449; called by muse, mutect2, varscan2
- ZSCAN5A | c.1173G>T p.K391N | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV54226473; called by muse, mutect2, varscan2
- AXIN2 | c.2244dup p.E749Rfs*15 | Frame Shift Ins (INS) | VAF 98/297 reads (33%) | called by mutect2, pindel, varscan2
- C4A | c.4112del p.G1371Efs*8 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, varscan2
- CHST2 | c.999del p.R335Afs*113 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- COL21A1 | c.2283del p.A763Qfs*38 | Frame Shift Del (DEL) | VAF 43/117 reads (37%) | called by mutect2, pindel, varscan2
- FOLH1B | n.1771-1G>T | Splice Site (SNP) | VAF 42/120 reads (35%) | called by muse, mutect2, varscan2
- FOXN2 | c.520del p.E174Kfs*28 | Frame Shift Del (DEL) | VAF 99/358 reads (28%) | called by mutect2, pindel, varscan2
- HTR6 | c.1180C>A p.L394I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IGHA2 | c.138G>C p.Q46H | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- IGKV1D-13 | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- LRRK1 | c.2483_2501del p.D828Afs*9 | Frame Shift Del (DEL) | VAF 26/58 reads (45%) | called by mutect2, pindel
- OR6M1 | c.354dup p.D119* | Frame Shift Ins (INS) | VAF 36/135 reads (27%) | called by mutect2, pindel, varscan2
- PCDH9 | c.473del p.N158Tfs*25 | Frame Shift Del (DEL) | VAF 101/370 reads (27%) | called by mutect2, pindel, varscan2
- PHF3 | c.1650dup p.Q551Tfs*3 | Frame Shift Ins (INS) | VAF 50/154 reads (32%) | called by mutect2, varscan2
- RBL2 | c.3415del p.H1139Tfs*8 | Frame Shift Del (DEL) | VAF 141/438 reads (32%) | called by mutect2, pindel, varscan2
- SBSN | c.1443del p.H481Qfs*65 (on ENST00000452271 / NM_001166034.2; = p.H138Qfs*65 on NM_198538.4) | Frame Shift Del (DEL) | VAF 31/80 reads (39%) | called by pindel, varscan2
- SLC30A10 | c.799del p.L267* | Frame Shift Del (DEL) | VAF 131/475 reads (28%) | called by pindel, varscan2
- TRAV26-1 | c.193A>C p.I65L | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- TRBV27 | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TRPC3 | c.1488del p.K497Nfs*6 (on ENST00000379645 / NM_001366479.2; = p.K424Nfs*6 on NM_003305.2) | Frame Shift Del (DEL) | VAF 104/234 reads (44%) | called by mutect2, pindel, varscan2
- TRPS1 | c.1854_1874del p.Q618_D625delinsH (on ENST00000220888 / NM_001330599.2; = p.Q631_D638delinsH on NM_014112.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 39/95 reads (41%) | called by mutect2, pindel, varscan2
- ADAMTS15 | c.1941C>T p.S647= | Silent (SNP) | VAF 65/160 reads (41%) | catalogued as rs770973237, COSV54503502; called by muse, mutect2, varscan2
- ADAMTS5 | c.1329T>A p.L443= | Silent (SNP) | VAF 38/118 reads (32%) | catalogued as COSV53178867; called by muse, mutect2, varscan2
- AKAP12 | c.2895C>T p.V965= | Silent (SNP) | VAF 85/296 reads (29%) | catalogued as rs774286589, COSV53574664; called by muse, mutect2, varscan2
- BCAR1 | c.1863G>C p.L621= | Silent (SNP) | VAF 44/128 reads (34%) | catalogued as rs777817468, COSV50782725; called by muse, mutect2, varscan2
- CCDC183 | c.189G>A p.K63= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV62012565, COSV62013632; called by muse, mutect2, varscan2
- CFHR3 | c.213T>C p.H71= | Silent (SNP) | VAF 134/321 reads (42%) | catalogued as COSV66402110; called by muse, mutect2, varscan2
- CHAF1B | c.270C>A p.I90= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as COSV58440051; called by muse, mutect2, varscan2
- CNTNAP2 | c.3844C>T p.L1282= | Silent (SNP) | VAF 60/154 reads (39%) | catalogued as COSV62177641; called by muse, mutect2, varscan2
- COL19A1 | c.2256G>T p.R752= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as COSV59572160; called by muse, mutect2, varscan2
- DMRTC2 | c.591G>C p.L197= | Silent (SNP) | VAF 119/202 reads (59%) | catalogued as rs782052285, COSV54186600; called by muse, mutect2, varscan2
- DNAH3 | c.4014G>T p.G1338= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as COSV54520261, COSV54534174; called by muse, mutect2, varscan2
- DNAH8 | c.6138T>A p.I2046= | Silent (SNP) | VAF 126/292 reads (43%) | catalogued as rs1483603641, COSV59443714; called by muse, varscan2
- DNAH8 | c.6159T>C p.D2053= | Silent (SNP) | VAF 66/242 reads (27%) | catalogued as rs765730505, COSV59443727; called by muse, varscan2
- DVL1 | c.1050A>G p.P350= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs776056866, COSV59563301; called by muse, mutect2, varscan2
- EBPL | c.9T>C p.A3= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs911699272, COSV54432280; called by muse, mutect2, varscan2
- EIF4EBP1 | c.156C>T p.I52= | Silent (SNP) | VAF 54/119 reads (45%) | catalogued as rs1468100078, COSV58774358; called by muse, mutect2, varscan2
- GCH1 | c.594G>T p.R198= | Silent (SNP) | VAF 93/332 reads (28%) | catalogued as COSV54301859; called by muse, mutect2, varscan2
- GDPD2 | c.825C>A p.L275= | Silent (SNP) | VAF 65/100 reads (65%) | catalogued as COSV65532854; called by muse, mutect2, varscan2
- GPA33 | c.237C>T p.Y79= | Silent (SNP) | VAF 43/150 reads (29%) | catalogued as COSV100900947, COSV63300954; called by muse, mutect2, varscan2
- GRIA2 | c.771C>G p.V257= | Silent (SNP) | VAF 181/315 reads (57%) | catalogued as COSV52389505, COSV99644749; called by muse, mutect2, varscan2
- HSPA12A | c.1507C>A p.R503= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV65022216, COSV65024108; called by muse, mutect2, varscan2
- IL9 | c.259C>T p.L87= | Silent (SNP) | VAF 75/124 reads (60%) | catalogued as COSV50853389; called by muse, mutect2, varscan2
- KCTD14 | c.705G>A p.T235= | Silent (SNP) | VAF 114/242 reads (47%) | catalogued as rs151197596; called by muse, mutect2, varscan2
- LBX1 | c.822C>T p.D274= | Silent (SNP) | VAF 83/197 reads (42%) | catalogued as COSV64621588; called by muse, mutect2, varscan2
- LONRF2 | c.1797G>C p.V599= | Silent (SNP) | VAF 130/394 reads (33%) | catalogued as COSV66540546; called by muse, mutect2, varscan2
- LRFN2 | c.483C>G p.L161= | Silent (SNP) | VAF 80/194 reads (41%) | catalogued as COSV57827175; called by muse, mutect2, varscan2
- LRP5 | c.2010G>T p.P670= | Silent (SNP) | VAF 48/112 reads (43%) | catalogued as COSV53715332; called by muse, mutect2, varscan2
- MAP2K2 | c.891G>T p.R297= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV53565158; called by muse, mutect2, varscan2
- MICAL3 | c.4992G>A p.K1664= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV71588282; called by muse, mutect2, varscan2
- MIER1 | c.72A>T p.P24= (on ENST00000355356 / NM_001077701.3; = p.P41= on NM_020948.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 129/354 reads (36%) | catalogued as COSV62529252, COSV62530121; called by muse, mutect2, varscan2
- MLN | c.99C>T p.G33= | Silent (SNP) | VAF 250/632 reads (40%) | catalogued as rs768851912, COSV56475192; called by muse, varscan2
- MUS81 | c.666G>T p.L222= | Silent (SNP) | VAF 59/164 reads (36%) | catalogued as rs1168382647, COSV57260073; called by muse, mutect2, varscan2
- NCAM1 | c.1093C>T p.L365= (on ENST00000316851 / NM_181351.5; = p.L355= on NM_000615.7) | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV57516078; called by muse, mutect2
- NOA1 | c.891G>T p.G297= | Silent (SNP) | VAF 42/67 reads (63%) | catalogued as COSV51736881; called by muse, mutect2, varscan2
- OPCML | c.522C>A p.V174= | Silent (SNP) | VAF 70/203 reads (34%) | catalogued as COSV59406656; called by muse, mutect2, varscan2
- OR8J3 | c.345G>A p.L115= | Silent (SNP) | VAF 128/391 reads (33%) | catalogued as rs377708276, COSV56880577; called by muse, mutect2, varscan2
- PCDH11X | c.3027C>G p.T1009= | Silent (SNP) | VAF 161/316 reads (51%) | catalogued as COSV53463458, COSV53466921; called by muse, mutect2, varscan2
- PCDHB4 | c.639G>C p.A213= | Silent (SNP) | VAF 170/245 reads (69%) | catalogued as COSV52022192; called by muse, mutect2, varscan2
- POTEE | c.381C>A p.A127= | Silent (SNP) | VAF 141/256 reads (55%) | catalogued as COSV58230292; called by muse, mutect2, varscan2
- PREX1 | c.3627G>A p.R1209= | Silent (SNP) | VAF 36/128 reads (28%) | catalogued as COSV64251481; called by muse, mutect2, varscan2
- PROX1 | c.1506C>T p.G502= | Silent (SNP) | VAF 18/410 reads (4%) | catalogued as COSV54778837; called by muse, mutect2
- PTPRO | c.2424C>A p.A808= | Silent (SNP) | VAF 168/288 reads (58%) | catalogued as COSV55509974; called by muse, mutect2, varscan2
- PXDN | c.750C>T p.S250= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs762530703, COSV53233278, COSV53243625; called by muse, mutect2, varscan2
- RAI1 | c.4398G>A p.R1466= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as COSV55392656; called by muse, mutect2, varscan2
- REPIN1 | c.1224C>T p.C408= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV68292222; called by mutect2, varscan2
- RIMBP2 | c.2115C>T p.D705= | Silent (SNP) | VAF 138/206 reads (67%) | catalogued as rs761677291, COSV55467808; called by muse, mutect2, varscan2
- SEC16A | c.2334G>C p.P778= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV51527114, COSV51527595; called by muse, mutect2, varscan2
- SERPINI1 | c.657G>A p.Q219= | Silent (SNP) | VAF 85/399 reads (21%) | catalogued as rs1187268609, COSV55510410; called by muse, mutect2, varscan2
- SEZ6L | c.1377C>T p.A459= | Silent (SNP) | VAF 43/140 reads (31%) | catalogued as COSV50663460; called by muse, mutect2, varscan2
- SLC12A9 | c.1482G>T p.A494= | Silent (SNP) | VAF 74/190 reads (39%) | catalogued as rs772006582, COSV51933225; called by muse, mutect2, varscan2
- SLC25A21 | c.462A>T p.A154= | Silent (SNP) | VAF 62/179 reads (35%) | catalogued as COSV58721067; called by muse, mutect2, varscan2
- SLC35F3 | c.577T>C p.L193= (on ENST00000366617 / NM_001300845.1; = p.L262= on NM_173508.4) | Silent (SNP) | VAF 84/235 reads (36%) | catalogued as COSV64019547; called by muse, varscan2
- SSTR4 | c.873C>T p.T291= | Silent (SNP) | VAF 100/328 reads (30%) | catalogued as rs199944012, COSV54798018, COSV99658371; called by muse, varscan2
- STAB2 | c.6885G>A p.V2295= | Silent (SNP) | VAF 131/214 reads (61%) | catalogued as COSV66338670; called by muse, mutect2, varscan2
- SULF2 | c.783C>A p.I261= | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as COSV63415827; called by muse, mutect2, varscan2
- TAAR5 | c.375C>A p.L125= | Silent (SNP) | VAF 90/254 reads (35%) | catalogued as COSV57798982; called by muse, varscan2
- TAF3 | c.45G>T p.A15= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs1474671405, COSV60206450; called by muse, mutect2, varscan2
- TMEM167B | c.147T>C p.A49= | Silent (SNP) | VAF 12/358 reads (3%) | catalogued as COSV57808174; called by muse, mutect2
- XKR4 | c.1185G>A p.S395= | Silent (SNP) | VAF 118/556 reads (21%) | catalogued as COSV59313998; called by muse, mutect2, varscan2
- ZIC1 | c.744C>A p.T248= | Silent (SNP) | VAF 64/222 reads (29%) | catalogued as COSV51553235; called by muse, mutect2, varscan2
- ZSCAN1 | c.963G>A p.P321= | Silent (SNP) | VAF 73/109 reads (67%) | catalogued as rs375333796, COSV99991887; called by muse, mutect2, varscan2
- CA5B | c.143-1695G>T | Intron (SNP) | VAF 9/13 reads (69%) | catalogued as rs1256959076, COSV59416003; called by muse, mutect2, varscan2
- ECPAS | chr9:111484477 A>C | 5'Flank (SNP) | VAF 10/22 reads (45%) | catalogued as COSV52196711; called by muse, mutect2, varscan2
- LINC02694 | n.401C>G | RNA (SNP) | VAF 36/71 reads (51%) | catalogued as COSV59558444, COSV59558686; called by muse, mutect2, varscan2
- MIR521-1 | n.16C>T | RNA (SNP) | VAF 114/223 reads (51%) | called by muse, mutect2, varscan2
- OPRM1 | c.1164+1946C>A | Intron (SNP) | VAF 176/606 reads (29%) | catalogued as COSV100002321; called by muse, mutect2, varscan2
- SV2C | c.581-21201C>A | Intron (SNP) | VAF 211/406 reads (52%) | called by mutect2, varscan2
- SV2C | c.581-21200A>T | Intron (SNP) | VAF 210/406 reads (52%) | called by mutect2, varscan2
- TBC1D29P | n.2550G>T | RNA (SNP) | VAF 10/31 reads (32%) | catalogued as COSV73694596; called by muse, mutect2, varscan2
- TTN | c.10360+4943C>T | Intron (SNP) | VAF 62/149 reads (42%) | catalogued as COSV60041345; called by muse, mutect2, varscan2
